Somatic mutation profile of tumor specimen ALCH-B281-TTP1-A (aliquot ALCH-B281-TTP1-A-1-0-D-A775-36) from ALCHEMIST case ALCH-B281, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 79.9 years (29,182 days).
Specimen ALCH-B281-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ae1b9bb-41ca-4c30-b06a-279b6f7b812a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B281-NB1-A (Blood Derived Normal), aliquot ALCH-B281-NB1-A-1-0-D-A775-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/961fa07c-162c-4287-bd17-a507c533c2a1

The open-access MAF lists 184 somatic variants for this specimen: 123 protein-altering or splice-affecting, 37 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 37, Intron 10, RNA 8, Nonsense Mutation 6, Frame Shift Del 4, Splice Site 3, 3'UTR 3, 5'Flank 2, Frame Shift Ins 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TRIO | c.2302C>T p.Q768* | Nonsense Mutation (SNP) | VAF 90/896 reads (10%) | catalogued as rs1554062562; ClinVar: pathogenic; called by muse, mutect2
- ADCY2 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 437/705 reads (62%) | catalogued as COSV57871006; called by muse, mutect2, varscan2
- AMIGO2 | c.174C>G p.N58K | Missense Mutation (SNP) | VAF 94/460 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.417); catalogued as COSV99873844; called by muse, mutect2, varscan2
- AP1M2 | c.1166G>A p.G389E | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1400232097; called by muse, mutect2, varscan2
- C6orf118 | c.564G>C p.Q188H | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.673); catalogued as rs1268918108; called by muse, mutect2, varscan2
- CCKAR | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 65/431 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs868034108, COSV55160045, COSV55164469; called by muse, mutect2, varscan2
- CEP72 | c.1758G>T p.Q586H | Missense Mutation (SNP) | VAF 83/484 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99374695; called by muse, varscan2
- CSMD2 | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs377466001; called by muse, mutect2, varscan2
- CSN1S1 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 43/252 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs376905625; called by muse, mutect2, varscan2
- CTNND2 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 34/497 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as COSV58912883; called by muse, mutect2
- DNAJC6 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.866); catalogued as rs1309466558; called by muse, mutect2, varscan2
- DZIP1 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61270751; called by muse, mutect2, varscan2
- ENKD1 | c.713A>G p.N238S | Missense Mutation (SNP) | VAF 84/230 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1393906470; called by muse, mutect2, varscan2
- EPHA3 | c.1234G>A p.V412I | Missense Mutation (SNP) | VAF 232/381 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs772463834, COSV60692526; called by muse, mutect2, varscan2
- H1-4 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.714); catalogued as COSV56800756; called by muse, mutect2, varscan2
- IQGAP2 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 40/374 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs769416675; called by muse, mutect2, varscan2
- LRRC4B | c.1883C>T p.S628L | Missense Mutation (SNP) | VAF 60/89 reads (67%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.022); catalogued as COSV65349441; called by muse, mutect2, varscan2
- NF1 | c.2851-1G>T p.X951_splice | Splice Site (SNP) | VAF 255/367 reads (69%) | catalogued as CD000081, CS1311517, COSV62220039; called by muse, mutect2, varscan2
- NR1I2 | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 93/421 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs750767310, COSV51772580; called by muse, mutect2, varscan2
- NRXN1 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 30/94 reads (32%) | catalogued as COSV68039489; called by muse, mutect2, varscan2
- OR4K17 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 41/315 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1566552301; called by muse, mutect2, varscan2
- PTPN12 | c.1427C>G p.S476C | Missense Mutation (SNP) | VAF 71/195 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.91); catalogued as rs766786152, COSV50373150; called by muse, mutect2, varscan2
- PTPRQ | c.2672C>T p.T891M (on ENST00000616559; = p.T849M on NM_001145026.2) | Missense Mutation (SNP) | VAF 38/388 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs974503422; called by muse, mutect2
- RNF17 | c.514C>T p.L172F | Missense Mutation (SNP) | VAF 67/134 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773571992; called by muse, mutect2, varscan2
- RTTN | c.6375T>G p.H2125Q | Missense Mutation (SNP) | VAF 67/287 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV55348792; called by muse, mutect2, varscan2
- SELL | c.916A>G p.T306A (on ENST00000650983; = p.T293A on NM_000655.5) | Missense Mutation (SNP) | VAF 24/884 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV99357984; called by muse, mutect2
- SETBP1 | c.3988T>A p.S1330T | Missense Mutation (SNP) | VAF 99/491 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV56321682; called by muse, mutect2, varscan2
- SLC6A19 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 46/576 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs200657233, COSV58673018; called by muse, mutect2
- SOCS4 | c.318G>T p.K106N | Missense Mutation (SNP) | VAF 28/592 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV104433226; called by muse, mutect2
- SOGA1 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 20/354 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs368608073; called by muse, mutect2
- SOX6 | c.398C>T p.T133I | Missense Mutation (SNP) | VAF 308/697 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1217600087; called by muse, mutect2, varscan2
- SPEF2 | c.4639C>A p.P1547T | Missense Mutation (SNP) | VAF 70/782 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV57430247; called by muse, mutect2
- SPOPL | c.84A>T p.K28N | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.849); catalogued as COSV54515938; called by muse, mutect2, varscan2
- TAF9B | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 20/401 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100540695; called by muse, mutect2
- TERT | c.1561C>A p.R521S | Missense Mutation (SNP) | VAF 335/515 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.425); catalogued as COSV57213263; called by muse, mutect2, varscan2
- USH2A | c.4603C>T p.H1535Y | Missense Mutation (SNP) | VAF 118/446 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV56398216; called by muse, mutect2, varscan2
- USP29 | c.586A>G p.K196E | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as rs1482296121, COSV54146183, COSV54147151; called by muse, mutect2, varscan2
- USP6 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 166/602 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.651); catalogued as rs754496085; called by muse, mutect2, varscan2
- UTRN | c.1636A>T p.T546S | Missense Mutation (SNP) | VAF 43/302 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as COSV62328996; called by muse, varscan2
- ZDHHC9 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 52/351 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs1165364635, COSV64096565; called by muse, mutect2, varscan2
- ZNF675 | c.869G>A p.G290D | Missense Mutation (SNP) | VAF 112/669 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); catalogued as COSV63097306; called by muse, mutect2, varscan2
- ZSCAN18 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.165); catalogued as rs1288731249, COSV74040040; called by muse, mutect2, varscan2
- ABCC8 | c.3650+1G>T p.X1217_splice | Splice Site (SNP) | VAF 89/398 reads (22%) | called by muse, mutect2, varscan2
- ACE2 | c.243A>T p.Q81H | Missense Mutation (SNP) | VAF 77/521 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- ADAMTSL1 | c.2351del p.K784Rfs*36 | Frame Shift Del (DEL) | VAF 58/340 reads (17%) | called by mutect2, pindel, varscan2
- ANGPTL5 | c.400C>A p.Q134K | Missense Mutation (SNP) | VAF 360/876 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANKRD26 | c.4766T>G p.V1589G | Missense Mutation (SNP) | VAF 101/924 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ARHGAP32 | c.4795A>T p.I1599F (on ENST00000310343 / NM_001378025.1; = p.I1250F on NM_014715.4) | Missense Mutation (SNP) | VAF 163/395 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ATP2B2 | c.3497G>T p.S1166I (on ENST00000352432; = p.S1132I on NM_001330611.3) | Missense Mutation (SNP) | VAF 38/380 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.228); called by muse, mutect2
- ATR | c.2610del p.T872Qfs*67 | Frame Shift Del (DEL) | VAF 22/135 reads (16%) | called by mutect2, pindel, varscan2
- CC2D1B | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CCDC148 | c.410T>C p.L137P | Missense Mutation (SNP) | VAF 74/589 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHAT | c.244T>A p.C82S | Missense Mutation (SNP) | VAF 105/478 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CHD4 | c.2808G>A p.M936I (on ENST00000357008 / NM_001363606.2; = p.M949I on NM_001273.5) | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.076); called by muse, mutect2
- CHPF | c.1484A>G p.E495G | Missense Mutation (SNP) | VAF 70/245 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRP | c.356A>T p.E119V | Missense Mutation (SNP) | VAF 109/763 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CUBN | c.7854A>C p.E2618D | Missense Mutation (SNP) | VAF 127/1149 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CUL4B | c.600G>C p.K200N | Missense Mutation (SNP) | VAF 53/371 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- CYP2U1 | c.1406_1407del p.D469Gfs*7 | Frame Shift Del (DEL) | VAF 25/245 reads (10%) | called by mutect2, pindel, varscan2
- DBN1 | c.406G>T p.G136W | Missense Mutation (SNP) | VAF 88/220 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMXL1 | c.1641G>C p.M547I | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH2 | c.7823C>T p.T2608I | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- DNAH2 | c.8362G>T p.V2788F | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- EYS | c.8839T>G p.L2947V (on ENST00000370621 / NM_001292009.1; = p.L2926V on NM_001142800.2) | Missense Mutation (SNP) | VAF 393/1213 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- F2R | c.1017C>A p.F339L | Missense Mutation (SNP) | VAF 91/536 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM172A | c.1106C>G p.A369G | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FAM71F1 | c.71A>G p.Y24C | Missense Mutation (SNP) | VAF 13/433 reads (3%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.819); called by muse, mutect2
- GATA2 | c.274A>G p.S92G | Missense Mutation (SNP) | VAF 121/388 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GLYR1 | c.439G>T p.V147L | Missense Mutation (SNP) | VAF 199/560 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- GNB2 | c.974T>C p.M325T | Missense Mutation (SNP) | VAF 58/319 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- GNL3L | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 103/391 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- GSX1 | c.113C>A p.A38E | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- HIVEP3 | c.7147C>T p.P2383S | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- HSPA1B | c.1634_1635insAA p.Y545* | Nonsense Mutation (INS) | VAF 143/729 reads (20%) | called by mutect2, pindel, varscan2
- ICAM5 | c.2461G>A p.G821R | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNB2 | c.1655C>G p.P552R | Missense Mutation (SNP) | VAF 47/295 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- KCNJ3 | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 73/469 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LDHB | c.405T>G p.I135M | Missense Mutation (SNP) | VAF 102/423 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- LRRC7 | c.4276C>G p.H1426D (on ENST00000651989 / NM_001370785.2; = p.H1346D on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/358 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- LTBR | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 186/411 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LYPLAL1 | c.456T>A p.N152K | Missense Mutation (SNP) | VAF 306/578 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAMDC2 | c.235_245del p.S79Ffs*25 | Frame Shift Del (DEL) | VAF 28/260 reads (11%) | called by mutect2, pindel, varscan2
- MAP3K11 | c.1041C>G p.C347W | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MBNL2 | c.709C>G p.P237A | Missense Mutation (SNP) | VAF 41/319 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- MYH7 | c.1243C>T p.Q415* | Nonsense Mutation (SNP) | VAF 138/422 reads (33%) | called by muse, mutect2, varscan2
- NIN | c.3676T>C p.F1226L | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.225); called by muse, mutect2
- NR1D1 | c.977C>T p.T326I | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ODR4 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.255); called by muse, mutect2
- OR6C4 | c.671T>C p.L224P | Missense Mutation (SNP) | VAF 128/685 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PHF8 | c.3122C>A p.T1041K (on ENST00000357988 / NM_001184896.1; = p.T1005K on NM_015107.3) | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- POR | c.1539dup p.M514Hfs*61 | Frame Shift Ins (INS) | VAF 63/213 reads (30%) | called by mutect2, pindel, varscan2
- PPM1A | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 131/399 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP2R5A | c.1255C>G p.L419V | Missense Mutation (SNP) | VAF 74/382 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRAG1 | c.2979G>T p.K993N | Missense Mutation (SNP) | VAF 125/341 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- PSTK | c.528G>C p.Q176H | Missense Mutation (SNP) | VAF 21/261 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RIMS1 | c.3527G>T p.R1176M | Missense Mutation (SNP) | VAF 58/441 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- RNF17 | c.1357A>T p.N453Y | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- RP1 | c.2870C>A p.P957H | Missense Mutation (SNP) | VAF 195/576 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- SCFD1 | c.602T>G p.F201C | Missense Mutation (SNP) | VAF 166/493 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SFT2D3 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 172/569 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SIRT2 | c.1015-1G>T p.X339_splice | Splice Site (SNP) | VAF 57/381 reads (15%) | called by muse, mutect2, varscan2
- SLC24A1 | c.1787A>C p.Y596S | Missense Mutation (SNP) | VAF 89/642 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SLC8A1 | c.368C>A p.T123N | Missense Mutation (SNP) | VAF 195/449 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- SLFN11 | c.2107G>T p.D703Y | Missense Mutation (SNP) | VAF 531/724 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMC6 | c.556G>T p.V186F | Missense Mutation (SNP) | VAF 130/374 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SNX13 | c.2208A>G p.I736M | Missense Mutation (SNP) | VAF 78/239 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- SV2C | c.1105A>G p.R369G | Missense Mutation (SNP) | VAF 51/272 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- TAOK3 | c.1141A>G p.M381V | Missense Mutation (SNP) | VAF 61/575 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TASP1 | c.550C>G p.P184A | Missense Mutation (SNP) | VAF 80/636 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- TCOF1 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); called by muse, mutect2
- TDRD6 | c.3910G>A p.G1304R | Missense Mutation (SNP) | VAF 17/274 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- THBS2 | c.58C>A p.H20N | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.005); called by muse, varscan2
- THRB | c.793G>C p.D265H | Missense Mutation (SNP) | VAF 218/1213 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRBV4-1 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 114/670 reads (17%) | called by muse, mutect2, varscan2
- TRHR | c.656T>C p.F219S | Missense Mutation (SNP) | VAF 80/543 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- TRIM77 | c.217C>A p.Q73K | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- TTLL8 | c.967A>G p.N323D | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- UBE4A | c.1001_1002insA p.S335Efs*127 (on ENST00000252108 / NM_001204077.2; = p.S342Efs*127 on NM_004788.4) | Frame Shift Ins (INS) | VAF 49/347 reads (14%) | called by mutect2, pindel, varscan2
- USP39 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- USP40 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 60/535 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- VCAN | c.1139C>G p.P380R | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- VPS39 | c.750G>T p.M250I (on ENST00000348544 / NM_001301138.2; = p.M239I on NM_015289.5) | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.005); called by mutect2, varscan2
- ZBTB40 | c.619C>A p.P207T | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.076); called by muse, mutect2
- ACO1 | c.2316A>G p.K772= | Silent (SNP) | VAF 78/454 reads (17%) | catalogued as rs748865716; called by muse, mutect2, varscan2
- ANGPTL1 | c.357G>A p.L119= | Silent (SNP) | VAF 62/1108 reads (6%) | called by muse, mutect2
- ATP6V0A2 | c.873C>T p.A291= | Silent (SNP) | VAF 62/434 reads (14%) | catalogued as rs1345427181; called by muse, mutect2, varscan2
- ATP8B4 | c.1587T>C p.Y529= | Silent (SNP) | VAF 70/354 reads (20%) | called by muse, mutect2, varscan2
- C6orf132 | c.1968A>G p.T656= | Silent (SNP) | VAF 157/911 reads (17%) | catalogued as rs1277532897; called by muse, mutect2, varscan2
- CACNA2D2 | c.969T>C p.D323= | Silent (SNP) | VAF 180/300 reads (60%) | called by muse, mutect2, varscan2
- CBLN4 | c.447C>G p.A149= | Silent (SNP) | VAF 265/799 reads (33%) | called by muse, mutect2, varscan2
- CCDC39 | c.474C>A p.L158= | Silent (SNP) | VAF 54/278 reads (19%) | called by muse, mutect2, varscan2
- CDC42EP2 | c.549G>T p.L183= | Silent (SNP) | VAF 27/166 reads (16%) | called by muse, mutect2, varscan2
- CEP72 | c.1701G>A p.E567= | Silent (SNP) | VAF 109/656 reads (17%) | called by muse, varscan2
- COL6A5 | c.4638C>A p.G1546= | Silent (SNP) | VAF 43/316 reads (14%) | called by muse, mutect2
- CYP11B2 | c.1254G>A p.P418= | Silent (SNP) | VAF 68/616 reads (11%) | catalogued as rs1430498116, COSV59995558; called by muse, mutect2, varscan2
- ENPP1 | c.1968T>A p.T656= | Silent (SNP) | VAF 45/527 reads (9%) | called by muse, mutect2
- HELZ2 | c.4476C>T p.F1492= (on ENST00000467148 / NM_001037335.2; = p.F923= on NM_033405.3) | Silent (SNP) | VAF 66/204 reads (32%) | called by muse, mutect2, varscan2
- HUWE1 | c.1047T>C p.C349= | Silent (SNP) | VAF 16/424 reads (4%) | called by muse, mutect2
- IQCA1 | c.1437A>G p.K479= | Silent (SNP) | VAF 58/563 reads (10%) | called by muse, mutect2
- KCNJ1 | c.882G>A p.V294= | Silent (SNP) | VAF 103/689 reads (15%) | called by muse, mutect2, varscan2
- KRTAP19-8 | c.18C>T p.S6= | Silent (SNP) | VAF 82/225 reads (36%) | called by muse, mutect2, varscan2
- LDOC1 | c.231G>A p.V77= | Silent (SNP) | VAF 235/735 reads (32%) | called by muse, mutect2, varscan2
- LRFN5 | c.864C>T p.L288= | Silent (SNP) | VAF 80/439 reads (18%) | catalogued as COSV53254697; called by muse, mutect2, varscan2
- MAP1B | c.4152G>A p.V1384= | Silent (SNP) | VAF 62/312 reads (20%) | called by muse, mutect2, varscan2
- MUC16 | c.18108C>T p.S6036= | Silent (SNP) | VAF 243/404 reads (60%) | catalogued as rs550938572, COSV67478536, COSV67487013; called by muse, mutect2, varscan2
- MYO15B | c.5367G>A p.Q1789= | Silent (SNP) | VAF 53/317 reads (17%) | called by muse, mutect2, varscan2
- NR0B1 | c.669G>A p.A223= | Silent (SNP) | VAF 37/325 reads (11%) | catalogued as rs1311357786; called by muse, mutect2, varscan2
- OR52E4 | c.798C>T p.G266= | Silent (SNP) | VAF 50/295 reads (17%) | catalogued as rs1022200355, COSV100389191; called by muse, mutect2, varscan2
- OTOL1 | c.672C>T p.G224= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs772954650, COSV60006150; called by muse, varscan2
- RTL1 | c.3189C>T p.F1063= | Silent (SNP) | VAF 31/196 reads (16%) | called by muse, mutect2, varscan2
- SAGE1 | c.1812A>T p.A604= | Silent (SNP) | VAF 79/609 reads (13%) | called by muse, mutect2, varscan2
- SBSN | c.1653C>T p.S551= (on ENST00000452271 / NM_001166034.2; = p.S208= on NM_198538.4) | Silent (SNP) | VAF 32/287 reads (11%) | catalogued as rs539647237, COSV101510030, COSV71733067; called by muse, mutect2, varscan2
- SERPINE1 | c.876G>A p.L292= | Silent (SNP) | VAF 152/366 reads (42%) | called by muse, mutect2, varscan2
- SGMS1 | c.738G>A p.P246= | Silent (SNP) | VAF 38/228 reads (17%) | catalogued as rs759281143, COSV62370996; called by muse, mutect2, varscan2
- SLAMF9 | c.39C>A p.L13= | Silent (SNP) | VAF 32/626 reads (5%) | called by muse, mutect2
- SLC22A9 | c.1638G>A p.P546= | Silent (SNP) | VAF 56/407 reads (14%) | catalogued as rs192219452; called by muse, mutect2, varscan2
- SLC9C2 | c.3018T>C p.F1006= | Silent (SNP) | VAF 35/344 reads (10%) | called by muse, mutect2
- SYNE1 | c.18606T>C p.V6202= (on ENST00000367255 / NM_182961.4; = p.V6131= on NM_033071.3) | Silent (SNP) | VAF 334/1032 reads (32%) | called by muse, mutect2, varscan2
- SYP | c.783G>T p.G261= | Silent (SNP) | VAF 18/165 reads (11%) | called by muse, mutect2, varscan2
- TAF3 | c.1362C>T p.S454= | Silent (SNP) | VAF 87/336 reads (26%) | catalogued as rs751887737, COSV60213020; called by muse, mutect2, varscan2
- AC073348.1 | n.137G>A | RNA (SNP) | VAF 61/459 reads (13%) | called by muse, mutect2, varscan2
- ADAMTS10 | c.435+23C>T | Intron (SNP) | VAF 18/212 reads (8%) | catalogued as rs542133595, COSV99546839; called by muse, mutect2
- AP000769.5 | chr11:65499770 A>G | 5'Flank (SNP) | VAF 26/175 reads (15%) | catalogued as rs1442383076; called by muse, mutect2, varscan2
- API5 | c.*108A>G | 3'UTR (SNP) | VAF 20/430 reads (5%) | called by muse, mutect2
- ARHGAP36 | c.-227C>T | 5'UTR (SNP) | VAF 10/107 reads (9%) | catalogued as rs1304221920; called by muse, mutect2
- CCNQP1 | n.424G>A | RNA (SNP) | VAF 18/321 reads (6%) | called by muse, mutect2
- CDON | c.1852-46C>G | Intron (SNP) | VAF 77/480 reads (16%) | called by muse, mutect2, varscan2
- ELN | chr7:74028165 G>T | 5'Flank (SNP) | VAF 34/113 reads (30%) | catalogued as rs782404948; called by muse, mutect2, varscan2
- GDPD1 | c.*1405G>A | 3'UTR (SNP) | VAF 68/445 reads (15%) | called by muse, mutect2, varscan2
- HIF3A | c.770+1317C>T | Intron (SNP) | VAF 9/73 reads (12%) | catalogued as rs753114357; called by muse, mutect2
- LILRB4 | c.988+20G>T | Intron (SNP) | VAF 67/118 reads (57%) | called by muse, mutect2, varscan2
- MDS2 | n.120T>C | RNA (SNP) | VAF 20/128 reads (16%) | catalogued as rs749674447; called by muse, mutect2, varscan2
- NLRX1 | c.*394C>G | 3'UTR (SNP) | VAF 42/297 reads (14%) | called by muse, mutect2, varscan2
- OVCH1-AS1 | n.555G>T | RNA (SNP) | VAF 86/186 reads (46%) | called by muse, mutect2, varscan2
- OVCH1-AS1 | n.556G>T | RNA (SNP) | VAF 86/184 reads (47%) | called by muse, mutect2, varscan2
- PRKAG2 | c.115-20956C>T | Intron (SNP) | VAF 66/641 reads (10%) | catalogued as rs770303164; called by muse, mutect2, varscan2
- RASGRP1 | c.1721-109A>C | Intron (SNP) | VAF 53/484 reads (11%) | catalogued as rs780975470; called by muse, mutect2, varscan2
- SKA2P1 | n.372T>G | RNA (SNP) | VAF 35/333 reads (11%) | called by muse, mutect2, varscan2
- SLC12A5 | c.1464-11C>A | Intron (SNP) | VAF 43/257 reads (17%) | called by muse, mutect2, varscan2
- SLC4A8 | c.1102-40G>A | Intron (SNP) | VAF 15/279 reads (5%) | called by muse, mutect2
- SPACA7 | c.94+2238T>G | Intron (SNP) | VAF 61/392 reads (16%) | called by muse, mutect2, varscan2
- TBC1D1 | c.1911-2144A>G | Intron (SNP) | VAF 16/156 reads (10%) | called by muse, mutect2
- TBC1D29P | n.2665G>C | RNA (SNP) | VAF 23/181 reads (13%) | called by muse, mutect2, varscan2
- TTC3P1 | n.5476C>A | RNA (SNP) | VAF 119/349 reads (34%) | called by muse, mutect2, varscan2
